Somatic mutation profile of tumor specimen TCGA-DD-AADQ-01A (aliquot TCGA-DD-AADQ-01A-11D-A40R-10) from TCGA case TCGA-DD-AADQ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 59.6 years (21,756 days).
Specimen TCGA-DD-AADQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0250cc43-63ae-4189-a9bc-ee6bc741d1fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AADQ-10A (Blood Derived Normal), aliquot TCGA-DD-AADQ-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a3edfb7-8e25-4bf4-a3a1-cd5c5005f739

The open-access MAF lists 134 somatic variants for this specimen: 104 protein-altering or splice-affecting, 27 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 27, Frame Shift Del 5, Nonsense Mutation 5, Splice Site 5, 5'UTR 2, Splice Region 2, 3'UTR 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM2 | c.365A>T p.N122I | Missense Mutation (SNP) | VAF 82/395 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99697780; called by muse, mutect2, varscan2
- ADGRG4 | c.7264G>T p.A2422S | Missense Mutation (SNP) | VAF 164/205 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99796461; called by muse, mutect2, varscan2
- AL136295.1 | c.464A>T p.D155V | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV99841873; called by muse, mutect2, varscan2
- AOX1 | c.3100C>T p.L1034F | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.82); catalogued as COSV99613771; called by muse, mutect2, varscan2
- AREG | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 486/1180 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756509675; called by muse, varscan2
- ARGFX | c.466C>A p.P156T | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); catalogued as COSV100544101; called by muse, mutect2, varscan2
- BCL3 | c.770C>T p.T257I | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as rs746104910, COSV99378306; called by muse, mutect2, varscan2
- C20orf96 | c.103A>G p.T35A (on ENST00000360321 / NM_153269.3; = p.T34A on NM_080571.1) | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV100826822; called by muse, mutect2, varscan2
- C2orf73 | c.614C>A p.S205Y | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV100471467, COSV58312077; called by muse, mutect2, varscan2
- CACNA2D1 | c.2765C>T p.P922L (on ENST00000356253 / NM_001366867.1; = p.P910L on NM_000722.4) | Missense Mutation (SNP) | VAF 95/224 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100667118; called by muse, mutect2, varscan2
- CACNB2 | c.1753C>T p.H585Y (on ENST00000324631 / NM_201596.3; = p.H530Y on NM_000724.4) | Missense Mutation (SNP) | VAF 72/186 reads (39%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.985); catalogued as rs772557073, COSV99996082; called by muse, mutect2, varscan2
- CCDC68 | c.398G>A p.R133K | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV61603089; called by muse, mutect2, varscan2
- CCDC86 | c.346T>C p.C116R | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs762413004, COSV99920287; called by muse, mutect2, varscan2
- COL6A6 | c.6182T>C p.I2061T | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as rs1392021080, COSV100650827; called by muse, mutect2, varscan2
- CPXCR1 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 186/218 reads (85%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV99342386; called by muse, mutect2, varscan2
- CTAGE1 | c.357A>T p.E119D | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV101194661; called by muse, mutect2, varscan2
- DENND6A | c.652G>T p.V218L | Missense Mutation (SNP) | VAF 518/1267 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV100231607; called by muse, mutect2, varscan2
- DOCK8 | c.5002G>A p.A1668T | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as rs759524696, COSV101210051; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC1H1 | c.10670A>T p.D3557V | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100795304; called by muse, mutect2, varscan2
- EAF2 | c.336A>C p.T112= | Splice Region (SNP) | VAF 255/655 reads (39%) | catalogued as COSV99877622; called by muse, mutect2, varscan2
- ELAPOR2 | c.2663G>A p.G888E (on ENST00000450689 / NM_001142749.3; = p.G721E on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as rs771865743, COSV99789293; called by muse, mutect2, varscan2
- FAM71B | c.922C>T p.Q308* | Nonsense Mutation (SNP) | VAF 61/79 reads (77%) | catalogued as COSV100262274, COSV57229032; called by muse, mutect2, varscan2
- FBN2 | c.7327T>G p.Y2443D | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV99330168; called by muse, mutect2, varscan2
- FBN2 | c.3328G>A p.E1110K | Missense Mutation (SNP) | VAF 10/278 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.435); catalogued as COSV99330169; called by muse, mutect2
- FMN1 | c.2932C>G p.P978A (on ENST00000616417 / NM_001277313.2; = p.P755A on NM_001103184.4) | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100569239; called by muse, mutect2, varscan2
- FN1 | c.3563C>A p.T1188N | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.756); catalogued as rs1350920539, COSV100118057; called by muse, mutect2, varscan2
- FZD4 | c.427C>A p.L143M | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.986); catalogued as COSV101536071, COSV72294264; called by muse, mutect2, varscan2
- GIGYF2 | c.3145A>G p.I1049V | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs371374687; called by muse, mutect2, varscan2
- GJB2 | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1291519904, CM031189, CM065231, COSV101241512; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR12 | c.532G>T p.G178C | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101197989, COSV101198018; called by muse, mutect2, varscan2
- GPRC6A | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100114696; called by muse, mutect2
- GRIK3 | c.2039C>T p.T680I | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100902258; called by muse, mutect2, varscan2
- GTF3C4 | c.593A>G p.N198S | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs1474103338, COSV100936074; called by muse, mutect2, varscan2
- GYPE | c.86C>T p.T29I | Missense Mutation (SNP) | VAF 188/426 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); catalogued as COSV100679444; called by muse, mutect2, varscan2
- IL6ST | c.149T>C p.L50P | Missense Mutation (SNP) | VAF 108/171 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100411008; called by muse, mutect2, varscan2
- ITGAM | c.1874T>C p.M625T (on ENST00000648685 / NM_001145808.2; = p.M624T on NM_000632.4) | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs754636547, COSV99793022; called by muse, mutect2, varscan2
- KCNA4 | c.137C>G p.A46G | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as COSV100069216, COSV60252671; called by muse, varscan2
- KDM1A | c.2434C>T p.H812Y | Missense Mutation (SNP) | VAF 98/125 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100174142; called by muse, mutect2, varscan2
- KLHL1 | c.753G>C p.E251D | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.09); catalogued as COSV100918008; called by muse, mutect2, varscan2
- KLHL2 | c.437G>T p.C146F | Missense Mutation (SNP) | VAF 104/213 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99900264; called by muse, mutect2, varscan2
- KRT16 | c.1328-1G>A p.X443_splice | Splice Site (SNP) | VAF 30/75 reads (40%) | catalogued as rs1265840224, COSV100053035; called by muse, mutect2, varscan2
- LIPG | c.685A>T p.S229C | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99724693; called by muse, mutect2, varscan2
- MAP1B | c.103A>C p.S35R | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.1); catalogued as COSV99702875; called by muse, mutect2, varscan2
- MAP2 | c.2474A>G p.D825G | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs780854358, COSV99561488; called by muse, mutect2, varscan2
- MBD5 | c.4402A>G p.M1468V | Missense Mutation (SNP) | VAF 136/347 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV101290244; called by muse, mutect2, varscan2
- MGA | c.6883G>C p.D2295H (on ENST00000219905 / NM_001164273.1; = p.D2086H on NM_001080541.2) | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99581275; called by muse, mutect2, varscan2
- MIA3 | c.1049A>G p.Y350C | Missense Mutation (SNP) | VAF 107/284 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.915); catalogued as COSV100719528; called by muse, mutect2, varscan2
- MYO7B | c.2767C>T p.P923S | Missense Mutation (SNP) | VAF 92/196 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); catalogued as COSV101268362; called by muse, mutect2, varscan2
- MYO9B | c.5882G>A p.R1961Q | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as rs373618149; called by muse, mutect2, varscan2
- NABP1 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 257/640 reads (40%) | catalogued as COSV100323100; called by muse, mutect2, varscan2
- NDUFAF2 | c.145A>G p.K49E | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as rs1031796945, COSV99681673; called by muse, mutect2, varscan2
- NOL6 | c.1769G>C p.R590P | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99955131; called by muse, mutect2, varscan2
- ODF2 | c.1844A>G p.D615G (on ENST00000434106 / NM_153433.2; = p.D591G on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV100654939; called by muse, mutect2, varscan2
- OR5D13 | c.370C>A p.R124S | Missense Mutation (SNP) | VAF 67/164 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV100686791; called by muse, mutect2, varscan2
- PACSIN3 | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 17/39 reads (44%) | catalogued as COSV100096556; called by muse, mutect2, varscan2
- PCDH9 | c.2620A>G p.R874G | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.602); catalogued as COSV100122978, COSV60583254; called by muse, mutect2, varscan2
- PCDHGA8 | c.547C>G p.Q183E | Missense Mutation (SNP) | VAF 82/317 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.117); catalogued as COSV53995770, COSV99545405; called by muse, mutect2, varscan2
- POTEH | c.16G>A p.G6S | Missense Mutation (SNP) | VAF 164/576 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as rs368142357, COSV100625038; called by muse, varscan2
- PRDX6 | c.521G>A p.R174K | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100458451, COSV100458499; called by muse, mutect2, varscan2
- PRPF4B | c.2923C>T p.Q975* | Nonsense Mutation (SNP) | VAF 433/615 reads (70%) | catalogued as COSV100528357; called by muse, mutect2, varscan2
- PTGER3 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 60/89 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60687791; called by muse, mutect2, varscan2
- PXDN | c.4178A>G p.Q1393R | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV99414710; called by muse, mutect2, varscan2
- RBMXL2 | c.712T>C p.Y238H | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV100182508; called by muse, mutect2, varscan2
- REV1 | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99301392; called by muse, mutect2, varscan2
- RUBCN | c.2116C>T p.P706S | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.245); catalogued as COSV99584927; called by muse, mutect2
- RUNDC1 | c.1220C>T p.T407I | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as COSV100865886; called by muse, mutect2, varscan2
- RYR1 | c.3044G>A p.R1015H | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as rs1202647394, COSV62089209; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAFB2 | c.2009T>G p.L670R | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs747436889, COSV99386034; called by muse, mutect2, varscan2
- SCN1A | c.3850T>A p.W1284R (on ENST00000303395 / NM_001202435.3; = p.W1273R on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/270 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100321771; called by muse, mutect2, varscan2
- SMARCA4 | c.3551T>C p.L1184P | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100759059; called by muse, mutect2, varscan2
- SORCS1 | c.177G>T p.Q59H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99549687; called by muse, mutect2, varscan2
- SSPOP | n.15117A>G | Splice Region (SNP) | VAF 14/33 reads (42%) | catalogued as rs1456997903, COSV100947938; called by muse, mutect2, varscan2
- STMN3 | c.347A>G p.E116G | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as COSV100899880; called by muse, mutect2, varscan2
- SUPT6H | c.4995-2A>G p.X1665_splice | Splice Site (SNP) | VAF 32/63 reads (51%) | catalogued as COSV99973031; called by muse, mutect2, varscan2
- SYCP2 | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 85/199 reads (43%) | catalogued as COSV100698420; called by muse, mutect2, varscan2
- TAS2R16 | c.783G>C p.W261C | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.259); catalogued as COSV99972328; called by muse, mutect2, varscan2
- TGFB1I1 | c.556A>C p.S186R (on ENST00000394863 / NM_001042454.3; = p.S169R on NM_015927.4) | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100691216; called by muse, mutect2, varscan2
- TNS3 | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 80/223 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV100236245; called by muse, mutect2, varscan2
- TTC1 | c.418A>T p.S140C | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV99180658; called by muse, mutect2, varscan2
- TTLL7 | c.113A>T p.K38M | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV99553027; called by muse, mutect2
- UBAP2L | c.1795A>T p.T599S | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.899); catalogued as COSV99672123; called by muse, mutect2, varscan2
- UGT1A3 | c.779A>G p.D260G | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100530875; called by muse, varscan2
- USP20 | c.2301-1G>T p.X767_splice | Splice Site (SNP) | VAF 60/159 reads (38%) | catalogued as COSV100204692; called by muse, mutect2, varscan2
- USP43 | c.1700A>T p.Q567L | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV99556995; called by muse, mutect2, varscan2
- UTRN | c.6520-2A>G p.X2174_splice | Splice Site (SNP) | VAF 25/39 reads (64%) | catalogued as COSV100840440; called by muse, mutect2, varscan2
- VAV3 | c.1794G>T p.Q598H | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.793); catalogued as COSV58393316; called by muse, mutect2
- VPS13A | c.3137A>T p.N1046I | Missense Mutation (SNP) | VAF 127/325 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.021); catalogued as COSV100653368; called by muse, mutect2, varscan2
- ZBTB9 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 90/148 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.259); catalogued as rs767106096, COSV101221795, COSV67702226; called by muse, mutect2, varscan2
- ZMYM6 | c.3385A>C p.S1129R | Missense Mutation (SNP) | VAF 23/395 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV100593319; called by muse, mutect2
- ZNF217 | c.1129T>A p.C377S | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100184756, COSV56596701; called by muse, mutect2, varscan2
- ZNF239 | c.1331C>T p.S444F | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100021895; called by muse, mutect2, varscan2
- ZNF347 | c.1414C>T p.L472F | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as COSV100498400; called by muse, mutect2, varscan2
- ZNF527 | c.1805G>T p.R602I | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs202094634, COSV100648771; called by muse, mutect2, varscan2
- ZNF99 | c.1835A>T p.Q612L | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV101233931; called by muse, mutect2
- ACOT11 | c.1303G>T p.D435Y | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2
- ALB | c.1212del p.V405Wfs*7 | Frame Shift Del (DEL) | VAF 136/358 reads (38%) | called by mutect2, pindel, varscan2
- AMY1C | c.100T>C p.W34R | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- DDX11 | c.1949-15_1949-1delinsAGA p.X650_splice | Splice Site (DEL) | VAF 18/66 reads (27%) | called by pindel, varscan2*
- ESRP2 | c.1526_1541del p.M509Rfs*12 (on ENST00000565858 / NM_001365264.1; = p.M499Rfs*12 on NM_024939.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | called by mutect2, pindel, varscan2
- FAM120C | c.887_889del p.E296del | In Frame Del (DEL) | VAF 88/116 reads (76%) | called by pindel, varscan2
- FMO3 | c.471del p.E158Sfs*6 | Frame Shift Del (DEL) | VAF 49/151 reads (32%) | called by mutect2, pindel, varscan2
- MTMR6 | c.1739_1747delinsTAAATGAT p.D580Vfs*6 | Frame Shift Del (DEL) | VAF 55/150 reads (37%) | called by pindel, varscan2*
- VAMP1 | c.296_297dup p.M100Sfs*12 | Frame Shift Ins (INS) | VAF 14/62 reads (23%) | called by mutect2, pindel, varscan2
- ZNF627 | c.1329_1338del p.E444Mfs*88 | Frame Shift Del (DEL) | VAF 13/26 reads (50%) | called by mutect2, pindel, varscan2
- ATP13A2 | c.1959C>A p.V653= | Silent (SNP) | VAF 56/79 reads (71%) | catalogued as COSV100454389; called by muse, mutect2, varscan2
- CARS2 | c.168C>T p.N56= | Silent (SNP) | VAF 39/67 reads (58%) | catalogued as COSV99959936; called by muse, mutect2, varscan2
- CCDC39 | c.630A>G p.A210= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as COSV99870402; called by muse, mutect2, varscan2
- CDH26 | c.1482T>C p.N494= | Silent (SNP) | VAF 43/88 reads (49%) | catalogued as COSV54845940; called by muse, mutect2, varscan2
- CDKN1A | c.175C>T p.L59= | Silent (SNP) | VAF 30/128 reads (23%) | catalogued as rs1366496685, COSV99781671; called by muse, mutect2, varscan2
- CNGB3 | c.99A>C p.P33= | Silent (SNP) | VAF 180/271 reads (66%) | catalogued as COSV100182907; called by muse, mutect2, varscan2
- DUSP9 | c.912C>T p.Y304= | Silent (SNP) | VAF 59/79 reads (75%) | catalogued as COSV100720169; called by muse, mutect2, varscan2
- ESYT3 | c.921G>A p.V307= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs914992530, COSV100004954; called by mutect2, varscan2
- HAS1 | c.1531C>T p.L511= | Silent (SNP) | VAF 42/104 reads (40%) | catalogued as rs751858625, COSV99708576; called by muse, mutect2, varscan2
- INSRR | c.1653C>G p.P551= | Silent (SNP) | VAF 44/115 reads (38%) | catalogued as COSV100947997; called by muse, mutect2, varscan2
- ITGAM | c.2349C>A p.I783= (on ENST00000648685 / NM_001145808.2; = p.I782= on NM_000632.4) | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV99793030; called by muse, mutect2, varscan2
- KIAA0232 | c.3141A>G p.P1047= | Silent (SNP) | VAF 41/121 reads (34%) | catalogued as rs549270762, COSV56930536; called by muse, mutect2, varscan2
- KIR3DL1 | c.156T>C p.R52= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV100428863; called by muse, varscan2
- LEMD1 | c.195T>C p.D65= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV100903480; called by muse, mutect2, varscan2
- LRP1B | c.2868A>T p.T956= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV101260001; called by muse, mutect2, varscan2
- MMP26 | c.714C>T p.F238= | Silent (SNP) | VAF 68/176 reads (39%) | catalogued as COSV100332235; called by muse, mutect2, varscan2
- MUC13 | c.951T>C p.F317= | Silent (SNP) | VAF 94/204 reads (46%) | catalogued as COSV100222479; called by muse, mutect2, varscan2
- MYO1C | c.1644G>T p.A548= (on ENST00000648651 / NM_001080779.2; = p.A513= on NM_033375.5) | Silent (SNP) | VAF 47/118 reads (40%) | catalogued as rs551011507, COSV62998433; called by muse, mutect2, varscan2
- NXPH2 | c.129G>A p.L43= | Silent (SNP) | VAF 53/133 reads (40%) | catalogued as COSV99741204; called by muse, mutect2, varscan2
- OR8J3 | c.90C>A p.V30= | Silent (SNP) | VAF 60/128 reads (47%) | catalogued as COSV100040945, COSV56880264; called by muse, mutect2, varscan2
- PCDHGC5 | c.2049C>T p.H683= | Silent (SNP) | VAF 40/174 reads (23%) | catalogued as COSV99341959; called by muse, mutect2, varscan2
- PLS3 | c.339C>T p.S113= | Silent (SNP) | VAF 216/257 reads (84%) | catalogued as rs1350956747, COSV99171945; called by muse, mutect2, varscan2
- PRR30 | c.393C>A p.S131= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as COSV99574773; called by muse, mutect2, varscan2
- RUBCN | c.2118A>T p.P706= | Silent (SNP) | VAF 46/120 reads (38%) | catalogued as COSV99584919; called by muse, mutect2
- SNCAIP | c.1491C>A p.A497= | Silent (SNP) | VAF 55/257 reads (21%) | catalogued as COSV54421852, COSV99750036; called by muse, mutect2, varscan2
- TMEM72 | c.15G>A p.V5= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs1170143876, COSV101273566; called by muse, mutect2, varscan2
- ZNF578 | c.645A>T p.S215= | Silent (SNP) | VAF 111/294 reads (38%) | catalogued as COSV101405113; called by muse, mutect2, varscan2
- COQ10B | c.-1C>A | 5'UTR (SNP) | VAF 92/214 reads (43%) | catalogued as COSV99827455; called by muse, mutect2, varscan2
- GGH | c.-1C>T | 5'UTR (SNP) | VAF 68/95 reads (72%) | catalogued as rs756079503, COSV99479007; called by muse, mutect2, varscan2
- XIRP2 | c.*1250G>A | 3'UTR (SNP) | VAF 178/465 reads (38%) | catalogued as rs766745683, COSV99746608; called by muse, mutect2, varscan2
